Somatic mutation profile of tumor specimen 0DHQED from CCDI case PBBUXE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 8.8 years (3,211 days).
Specimen 0DHQED: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d41782ca-078f-4eff-9fff-f0998efe26b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHQDG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2038876f-5f90-4d27-903e-bee2cb403299

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 2, Frame Shift Ins 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOT8 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 126/621 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as rs372761702, COSV54169294; called by muse, mutect2, varscan2
- HTR3A | c.871G>A p.V291I | Missense Mutation (SNP) | VAF 63/137 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.692); catalogued as rs756076645; called by muse, mutect2, varscan2
- INO80 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 136/736 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs202070069, COSV62741065; called by muse, mutect2, varscan2
- SCN9A | c.4654G>A p.V1552M (on ENST00000303354; = p.V1541M on NM_002977.3) | Missense Mutation (SNP) | VAF 358/835 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as rs1235052295; called by muse, mutect2, varscan2
- ZBTB41 | c.1072A>G p.K358E | Missense Mutation (SNP) | VAF 172/1001 reads (17%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.629); catalogued as COSV66358771; called by muse, mutect2, varscan2
- ZCWPW1 | c.1556C>T p.S519F | Missense Mutation (SNP) | VAF 123/528 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV52199921; called by muse, mutect2, varscan2
- ABCA12 | c.7344C>T p.S2448= (on ENST00000272895 / NM_173076.3; = p.S2130= on NM_015657.3) | Splice Region (SNP) | VAF 274/673 reads (41%) | called by muse, mutect2, varscan2
- ACOD1 | c.326T>G p.L109R | Missense Mutation (SNP) | VAF 238/534 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCNA1 | c.10G>A p.G4S | Missense Mutation (SNP) | VAF 267/575 reads (46%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 40/1460 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- IL23A | c.54G>T p.Q18H | Missense Mutation (SNP) | VAF 56/399 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- NFIA | c.1083_1090dup p.T364Sfs*36 | Frame Shift Ins (INS) | VAF 69/274 reads (25%) | called by mutect2, varscan2
- PCLO | c.10341G>A p.T3447= | Silent (SNP) | VAF 261/673 reads (39%) | catalogued as rs566457960, COSV61615170, COSV61629759; called by muse, mutect2, varscan2
- TRMT5 | c.1350C>T p.H450= | Silent (SNP) | VAF 261/617 reads (42%) | called by muse, mutect2, varscan2
- C1RL | chr12:7109222 G>C | 5'Flank (SNP) | VAF 31/164 reads (19%) | called by muse, mutect2, varscan2
